Gene-level copy-number profile of tumor specimen TCGA-56-8622-01A from TCGA case TCGA-56-8622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.1 years (24,861 days).
Specimen TCGA-56-8622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.824e0503-e7a1-482f-848e-b40f8b5489cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8622-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1933b8bc-8b21-4617-b2a6-bee60b9cbbd7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 225; copy number 1: 10,212; copy number 2: 37,373; copy number 3: 8,975; copy number 4: 1,397; copy number 5: 778; copy number 6: 14; copy number 7: 75; copy number 8: 92; copy number 9: 9; copy number 12: 529; copy number 14: 91; copy number 15: 5; copy number 21: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8622-01A-11D-2391-01): tumor purity 0.47, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 225 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:140,785,698–141,512,981, 81 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:16,726,814–17,503,923, 8 genes (within-gene range 0–1): BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN.
- chr9:38,433,696–38,543,880, 1 gene (within-gene range 0–1): AL390726.5.
- chr9:38,478,471–43,045,120, 134 genes (broad region; genes not listed).
- chr21:23,704,260–23,709,345, 1 gene: AP000961.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,632 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–19,260,128, 625 genes, copy number 5–8 (broad region; genes not listed).
- chr3:130,345,516–130,484,844, 1 gene, copy number 5 (within-gene range 2–5): COL6A5.
- chr3:161,600,438–161,821,908, 2 genes, copy number 5: AC112770.1, AC131211.1.
- chr4:10,143,367–10,295,579, 10 genes, copy number 6: AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–77,433,388, 4 genes, copy number 6 (within-gene range 2–6): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr5:58,198–45,895,970, 710 genes, copy number 8–14 (broad region; genes not listed).
- chr8:38,269,704–40,016,391, 39 genes, copy number 21 (within-gene range 1–21): NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1.
- chr19:39,236,433–40,426,702, 75 genes, copy number 7 (broad region; genes not listed).
- chr19:42,397,128–42,652,355, 1 gene, copy number 5 (within-gene range 3–5): LIPE-AS1.
- chr19:42,428,278–45,502,510, 151 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:41,402,083–43,189,970, 14 genes, copy number 9–15 (within-gene range 2–15): CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100.

Autosomal genes at a single copy (total copy number 1): 7,797. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
